Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DP, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DP-01A (Primary Tumor).

lw 10/21/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Left lobe

HISTOLOGIC TYPE: Papillary carcinoma

TUMOR SIZE: Greatest dimension 2.5 cm

FOCALITY: Unifocal

LYMPH NODES: None submitted

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2cm, but <4cm, limited to thyroid

REGIONAL LYMPH NODES:

pNx: Cannot be assessed.

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS: Margins are uninvolved.

VENOUS/LYMPHATIC INVASION: Absent

1cD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

lw
10/21/11

Source: NCI Genomic Data Commons file 8217b107-9440-4e59-b4e5-44a3eba7fb05 (TCGA-ET-A3DP.65943762-40CF-4F6D-8C1C-1CE807C02D6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).